Surgical pathology report (de-identified scan), TCGA case TCGA-AH-6547, project TCGA-READ (Rectum Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-AH-6547-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Omentum, excision:

Fat necrosis and fibrosis with scattered calcifications.
No diagnostic evidence of malignancy.
Frozen section diagnosis confirmed.

B. Rectosigmoid colon, excision:

Tumor Characteristics:

1. Histologic type: Adenocarcinoma
2. Location of tumor: Rectosigmoid colon.
3. Size: 4.5 x 3.8 cm.
4. Grade (If applicable to tumor type): 2/3, moderately differentiated.
5. Lymphovascular space invasion: Not identified.
6. Perforation of visceral peritoneum: Not identified.
7. Presence of mesenteric deposits: Not identified.
8. Depth of invasion/extent of invasion: Tumor focally penetrates through the muscularis propria into subserosal fat, extending approximately 0.1 cm from the border of the muscularis propria.
9. Astler-Coller classification: C1.
-

Surgical Margin Status:

1. Proximal margin: Negative.
2. Distal margin: Negative.
3. Deep (radial) margin: Negative.
4. Distance of tumor from closest margin: 2.2 cm (radial).

Lymph Node Status:

1. Total number of lymph nodes examined: 21.
2. Total number of lymph nodes containing metastatic carcinoma: 0.

Other:

1. pTNM stage: pT3b, N0, Mx.

C. Right colon, excision:

Tubular adenomas, with focal high-grade dysplasia.
No diagnostic evidence of invasive malignancy.
Maximum polyp size 5.5 x 2.8 cm.
Eight lymph nodes, negative for metastatic disease.
Additional fragments of mucosa with congestion.

CLINICAL INFORMATION

[page 2 of 2]
CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Known sigmoid colon carcinoma, omental mass

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Omentum, [REDACTED]
- B. Rectosigmoid colon
- C. Right colon

SPECIMEN DATA

GROSS DESCRIPTION:

A. Part A received labeled [REDACTED] and #1 omentum is a 3.5 x 3.1 x 1.8 cm irregular fibroadipose tissue. The cut surface consists of a 2.8 x 2.5 x 1.4 cm granular tan orange nodule. The remainder of the cut surface consists of predominantly yellow lobulated adipose tissue with a scant amount of gray white fibrous tissue. No additional lesions are identified. The specimen is serially sectioned and representative section is submitted for frozen section and the frozen section residue is submitted in block 1. Additional representative sections are submitted in blocks 2-4. The blocks are labeled [REDACTED]

B. Part B received labeled [REDACTED] and #2 rectosigmoid colon is a 19.8 cm segment of partially opened colon with a moderate amount of attached pericolic fat. The serosa is smooth and tan pink. There is a 4.5 x 3.8 cm granular tan mucosal lesion, 2.8 cm from the distal margin and 12.7 cm from the proximal margin. The cut surface of the mass is gray tan and appears to extend into the pericolic fat with a thickness of 0.8 cm. The mass is 2.2 cm from the inked pericolic fat. The remainder of the mucosa is tan with the normal folds. No additional mucosal lesions are identified. The proximal and distal inner circumferences average 1.1 and 3.5 cm, respectively, and the wall thickness averages 0.2 cm. There are multiple irregular tan yellow firm tissues consistent with probable lymph nodes ranging from 0.2 x 0.2 x 0.1 to 1.8 x 1.3 x 0.6 cm. The specimen is inked, sectioned and representative sections are submitted as labeled: 1--proximal margin (en-face); 2--distal margin (en-face); 3 and 4--lesion to underlying adipose tissue; 5 and 6--full thickness mass bisected; 7--mass to uninvolved parenchyma; 8 to 10--five whole probable lymph nodes in each; 11 and 12--three whole probable lymph nodes in each; 13 to 22--one probable lymph node bisected in each; 23 and 24--one lymph node trisected. The blocks are labeled [REDACTED]. Also received is a green and yellow cassette labeled [REDACTED] for genomic research study.

C. Part C received in formalin labeled [REDACTED] and #3 right colon is a 16.8 cm segment of partially opened colon with an attached 11.2 cm segment of terminal ileum and a moderate amount of pericolic fat. The appendix is not present. The serosa is smooth and tan pink. There is a 5.5 x 2.8 cm bosselated tan mucosal polyp, 1.5 cm from the ileocecal valve and 5.1 cm from the distal margin. The polyp does not involve the underlying muscularis. There are two additional smaller polyps in the cecum and cecal pouch measuring 0.3 and 1.5 x 1.1 cm. The remainder of the mucosa is tan with the normal folds. No additional obvious lesions are identified. The proximal and distal inner circumferences average 3.5 and 2.8 cm, respectively, and the wall thickness averages 0.2 cm. There are multiple irregular tan yellow firm tissues consistent with probable lymph nodes ranging from 0.3 x 0.2 x 0.2 cm to 1.5 x 0.5 x 0.4 cm.

Also received in the same container are two annular rims of tan mucosa averaging 2.2 x 1.5 x 1.0 cm.

The specimen is inked, sectioned and representative sections are submitted as labeled: 1--proximal and distal margins; 2--ileocecal valve; 3 to 6--largest polyp to inked serosa; 7 and 8--largest polyp; 9 and 10--smaller additional polyp entirely submitted; 11--smallest additional polyp entirely submitted; 12--five whole probable lymph nodes; 13--four whole probable lymph nodes; 14--three whole probable lymph nodes; 15--additional portions of mucosa. The blocks are [REDACTED]

Source: NCI Genomic Data Commons file fdb3e3eb-3c3d-4da7-bc8a-c7db7ac58502 (TCGA-AH-6547.93F0821C-BCCF-4E1E-A15E-602EAE6F1482.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).